Somatic mutation profile of tumor specimen TCGA-FS-A1ZW-06A (aliquot TCGA-FS-A1ZW-06A-12D-A197-08) from TCGA case TCGA-FS-A1ZW, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 67.8 years (24,759 days).
Specimen TCGA-FS-A1ZW-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9192d6ea-21cb-4789-b9ed-9119956bc16c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZW-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZW-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bd232fa-de0f-4819-a600-30f74f8c2573

The open-access MAF lists 780 somatic variants for this specimen: 526 protein-altering or splice-affecting, 238 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 476, Silent 238, Nonsense Mutation 34, Intron 7, Splice Site 7, 3'UTR 5, Frame Shift Del 3, Splice Region 2, Translation Start Site 2, 5'UTR 2, Frame Shift Ins 2, RNA 2.

Variants (750 of 780; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 245/521 reads (47%) | hotspot (GDC flag); catalogued as rs864622636, CM023895, COSV58683786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 65/210 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PCSK5 | c.2771G>A p.W924* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | hotspot (GDC flag); catalogued as COSV70451329; called by muse, mutect2, varscan2
- PPP6C | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs1481246558, COSV65207385; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 48/102 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABCB11 | c.3391G>A p.D1131N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55596397; called by muse, mutect2, varscan2
- ABCC4 | c.2986T>G p.C996G | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV65316152; called by muse, mutect2, varscan2
- ABCC8 | c.3892G>A p.V1298M | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56854705; called by muse, mutect2, varscan2
- ABLIM1 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53311382; called by muse, mutect2, varscan2
- ACAD10 | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs746299861, COSV58160438; called by muse, mutect2, varscan2
- ACTR8 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as rs201848227, COSV51636208; called by muse, mutect2, varscan2
- ADAM21 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV50801094; called by muse, varscan2
- ADAM29 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63660843, COSV63663413; called by muse, mutect2, varscan2
- ADAM29 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV63666064; called by muse, mutect2, varscan2
- ADAM7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1333012683, COSV51535711; called by muse, mutect2, varscan2
- ADAMTS12 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV61257243; called by muse, mutect2, varscan2
- ADAMTS20 | c.5336C>T p.P1779L | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67135908; called by muse, mutect2, varscan2
- ADAMTS3 | c.3197C>T p.A1066V | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.178); catalogued as COSV54397568; called by muse, mutect2, varscan2
- ADGRV1 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67985626; called by muse, mutect2, varscan2
- ADGRV1 | c.5879G>A p.G1960E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV67991289; called by muse, mutect2, varscan2
- ADH1A | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52925726; called by muse, varscan2
- ADTRP | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769008216, COSV57644797; called by muse, mutect2, varscan2
- AGTR1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762020328, CM1514785, COSV62557225, COSV62558442; called by muse, mutect2, varscan2
- AHCTF1 | c.1229C>T p.S410L (on ENST00000366508; = p.S384L on NM_015446.5) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58246164; called by muse, mutect2, varscan2
- AHNAK | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57223171; called by muse, mutect2, varscan2
- AKAP9 | c.9559G>T p.E3187* (on ENST00000359028; = p.E3163* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as COSV62353244; called by muse, mutect2, varscan2
- AL592490.1 | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV69425355, COSV69427187; called by muse, mutect2, varscan2
- ALMS1 | c.10160T>G p.V3387G | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52516545; called by muse, mutect2, varscan2
- ALPK3 | c.5107G>A p.G1703S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.183); catalogued as COSV99361003; called by muse, mutect2, varscan2
- ANK2 | c.3869C>T p.S1290F | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52147707; called by muse, mutect2, varscan2
- ANKH | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.69); PolyPhen probably damaging (1); catalogued as rs1290787571, COSV52484033; called by muse, mutect2, varscan2
- ANKRD12 | c.5129A>G p.Y1710C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs868775529, COSV50836675; called by muse, mutect2
- ANKRD17 | c.5845C>T p.H1949Y | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.954); catalogued as rs755982500, COSV58224966; called by muse, mutect2, varscan2
- ANKRD30A | c.1787G>A p.G596E (on ENST00000611781; = p.G540E on NM_052997.2) | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.938); catalogued as COSV64616394; called by muse, mutect2, varscan2
- ANXA6 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV62907599; called by muse, mutect2, varscan2
- APOB | c.10263G>A p.M3421I | Missense Mutation (SNP) | VAF 262/878 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV51933873; called by muse, mutect2, varscan2
- AREG | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as rs1283640826; called by muse, mutect2, varscan2
- ARMC12 | c.770G>A p.R257Q (on ENST00000373866 / NM_001286574.2; = p.R284Q on NM_145028.5) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs777525803, COSV55361079; called by muse, mutect2, varscan2
- ASXL3 | c.5043G>A p.M1681I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs1333935790, COSV52466476; called by muse, mutect2, varscan2
- AXDND1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV62645630; called by muse, mutect2, varscan2
- B3GNT7 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs899688441, COSV55006371; called by muse, mutect2, varscan2
- BANK1 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV59839694; called by muse, mutect2, varscan2
- BBOX1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs1385738688, COSV54192766; called by muse, mutect2
- BCL6B | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770283128, COSV53427614; called by muse, mutect2, varscan2
- BLNK | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs1351358939, COSV56413321; called by muse, mutect2
- BPTF | c.4619C>T p.P1540L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV58842959; called by muse, mutect2, varscan2
- C1orf87 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs772529746, COSV64598000, COSV64599212; called by muse, mutect2, varscan2
- C2CD3 | c.1750C>T p.H584Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV58096879; called by muse, mutect2, varscan2
- C9orf131 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV56612775; called by muse, mutect2, varscan2
- C9orf43 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV55913454; called by muse, mutect2, varscan2
- C9orf72 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1448530665, COSV66154947; called by muse, mutect2, varscan2
- CACNA1C | c.5080G>A p.D1694N | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV59750141; called by muse, mutect2, varscan2
- CACNG3 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV50076683; called by muse, mutect2, varscan2
- CACNG3 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.385); catalogued as rs771108279, COSV50076755; called by muse, mutect2, varscan2
- CAMK1D | c.304T>A p.S102T | Missense Mutation (SNP) | VAF 121/336 reads (36%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.99); catalogued as COSV66616466; called by muse, mutect2, varscan2
- CAMKV | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV56556828; called by muse, mutect2, varscan2
- CAMTA2 | c.3546-1G>A p.X1182_splice | Splice Site (SNP) | VAF 19/104 reads (18%) | catalogued as COSV99236552; called by muse, mutect2, varscan2
- CAPSL | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.026); catalogued as COSV68438907; called by muse, mutect2, varscan2
- CAPZA3 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99856427; called by muse, mutect2, varscan2
- CARF | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 98/388 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57548955; called by muse, mutect2, varscan2
- CARMIL2 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as COSV58029732; called by muse, mutect2, varscan2
- CASP5 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52827926, COSV52830459; called by muse, mutect2, varscan2
- CCAR2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.88); catalogued as COSV57906881; called by muse, mutect2, varscan2
- CCDC146 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV53552019; called by muse, mutect2, varscan2
- CCDC191 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV55673995; called by muse, mutect2, varscan2
- CCDC57 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV58936358; called by muse, mutect2, varscan2
- CCDC92 | c.657A>C p.E219D | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV53020914; called by muse, mutect2, varscan2
- CCER1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV100727100, COSV62647956; called by muse, mutect2, varscan2
- CCN5 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV51938394; called by muse, mutect2, varscan2
- CCNA1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV55222987; called by muse, mutect2, varscan2
- CCNA1 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1273259772, COSV55222575; called by muse, mutect2, varscan2
- CCT7 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 78/248 reads (31%) | catalogued as COSV54587532; called by muse, mutect2, varscan2
- CD163 | c.2630C>T p.P877L | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV63135552; called by muse, mutect2, varscan2
- CD248 | c.644A>G p.K215R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as COSV60937336; called by muse, mutect2, varscan2
- CD59 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV60919625; called by muse, mutect2, varscan2
- CD86 | c.704-1G>A p.X235_splice (on ENST00000330540 / NM_175862.5; = p.X229_splice on NM_006889.4) | Splice Site (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100053906, COSV52605464, COSV52608741; called by muse, mutect2, varscan2
- CDC27 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV50628101; called by muse, mutect2, varscan2
- CDC27 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs150116111; called by muse, mutect2, varscan2
- CDH18 | c.233A>C p.H78P | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56944598; called by muse, mutect2, varscan2
- CDH5 | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs527919138, COSV100439259; called by muse, varscan2
- CDHR3 | c.2012G>A p.G671E | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58419760; called by muse, mutect2, varscan2
- CDHR3 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58419780; called by muse, mutect2
- CDX4 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV65171801; called by muse, mutect2, varscan2
- CELSR1 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748727636, COSV53095584; called by muse, mutect2, varscan2
- CEP162 | c.3214C>T p.Q1072* | Nonsense Mutation (SNP) | VAF 20/136 reads (15%) | catalogued as COSV57622285; called by muse, mutect2, varscan2
- CEP164 | c.1673A>T p.D558V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV54044175; called by muse, mutect2, varscan2
- CEP95 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs782810955, COSV56750451, COSV56750466; called by muse, mutect2, varscan2
- CFAP58 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs746292556, COSV57211513; called by muse, mutect2, varscan2
- CFHR2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as COSV100804371, COSV66380555; called by muse, mutect2, varscan2
- CHL1 | c.1999G>A p.G667R (on ENST00000397491 / NM_001253387.1; = p.G683R on NM_006614.4) | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772617465, COSV56599730, COSV56607626; called by muse, mutect2, varscan2
- CHST5 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV60340715; called by muse, mutect2, varscan2
- CLASP2 | c.4216C>T p.P1406S (on ENST00000359576; = p.P1405S on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV56289291; called by muse, mutect2, varscan2
- CLDN1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs537860492, COSV55044655; called by muse, mutect2, varscan2
- CLEC14A | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV60563585; called by muse, mutect2, varscan2
- CMYA5 | c.4153C>T p.R1385C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV71408061; called by muse, mutect2, varscan2
- CNR1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs267601156; called by muse, mutect2, varscan2
- CNTN4 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs548348880, COSV100639315, COSV61868614; called by muse, mutect2, varscan2
- COL11A1 | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1267946269, COSV62190573; called by muse, mutect2, varscan2
- COL12A1 | c.5441A>G p.K1814R | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0.186); catalogued as COSV59402411; called by muse, mutect2, varscan2
- COL14A1 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV52861676; called by muse, mutect2, varscan2
- CRYBA4 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61322496; called by muse, mutect2, varscan2
- CSMD1 | c.8228G>A p.G2743E (on ENST00000520002; = p.G2742E on NM_033225.6) | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59355537; called by muse, mutect2, varscan2
- CSMD1 | c.6940C>T p.P2314S (on ENST00000520002; = p.P2313S on NM_033225.6) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100142579, COSV59315223; called by muse, mutect2, varscan2
- CSMD2 | c.9134C>T p.S3045F | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53938817; called by muse, mutect2, varscan2
- CSMD2 | c.4133C>T p.S1378L | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV53906670; called by muse, mutect2, varscan2
- CTAGE1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 123/304 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as rs541555782, COSV66943124; called by muse, mutect2, varscan2
- CYLC2 | c.227G>A p.W76* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100872407, COSV66338727; called by muse, mutect2, varscan2
- CYP11B2 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs1260050342, COSV59997128; called by muse, mutect2, varscan2
- DACH2 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV64162958, COSV64163426; called by muse, mutect2, varscan2
- DCAF4L1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 47/185 reads (25%) | catalogued as COSV60788067; called by muse, mutect2, varscan2
- DCN | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1440753591, COSV50006030, COSV50008234, COSV99271780; called by muse, mutect2, varscan2
- DDR1 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.091); catalogued as COSV100241589; called by muse, mutect2, varscan2
- DDR1 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs199740590, COSV100241592, COSV61319586; called by muse, mutect2, varscan2
- DDX43 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV64837566; called by muse, mutect2, varscan2
- DDX53 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60069527; called by muse, mutect2, varscan2
- DICER1 | c.5107C>A p.R1703S | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58624724, COSV58624882; called by muse, mutect2, varscan2
- DLGAP2 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV70095633; called by muse, mutect2
- DMTN | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV56113718; called by muse, mutect2, varscan2
- DNAH11 | c.5500C>T p.R1834C | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs180897552, CM140771, COSV60944662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66723225; called by muse, mutect2, varscan2
- DNAH3 | c.1246A>C p.K416Q | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as COSV99767782; called by muse, varscan2
- DNAH5 | c.9706G>A p.D3236N | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs374206128, COSV99451113; called by muse, mutect2, varscan2
- DNAH5 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs749610202, COSV54203222; called by muse, mutect2, varscan2
- DNAH7 | c.250+1G>A p.X84_splice | Splice Site (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100415410; called by muse, mutect2, varscan2
- DNAH8 | c.7514G>A p.R2505Q | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330298296, COSV59428426; called by muse, mutect2, varscan2
- DNAH8 | c.12744G>A p.M4248I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs972829158, COSV59467121; called by muse, mutect2, varscan2
- DNAI1 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs774157246, COSV54283163; called by muse, mutect2, varscan2
- DNAJC5B | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs368879135; called by muse, mutect2, varscan2
- DOK1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99284080; called by muse, mutect2, varscan2
- DOP1B | c.5006G>A p.R1669K | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs1190510380, COSV67694725; called by muse, mutect2, varscan2
- DPRX | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs761892759, COSV64949245; called by muse, mutect2, varscan2
- DPY19L4 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 153/545 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV68963449; called by muse, mutect2, varscan2
- DPY19L4 | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 108/432 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV68963453; called by muse, mutect2, varscan2
- DRGX | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV65137017; called by muse, mutect2, varscan2
- DSCAM | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV68648847; called by muse, mutect2, varscan2
- DSCAML1 | c.4085C>T p.P1362L (on ENST00000321322; = p.P1302L on NM_020693.4) | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401216034, COSV100356103; called by muse, mutect2, varscan2
- DSCAML1 | c.4084C>T p.P1362S (on ENST00000321322; = p.P1302S on NM_020693.4) | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100356104; called by muse, mutect2, varscan2
- DSG1 | c.2393C>A p.P798Q | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV57137818; called by muse, mutect2
- E4F1 | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs542965861, COSV57040368; called by muse, mutect2, varscan2
- ECE1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51668276; called by muse, mutect2, varscan2
- EEF1A2 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.146); catalogued as rs1390133779, COSV53207357; called by muse, mutect2, varscan2
- EEF2K | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV53784849; called by muse, mutect2, varscan2
- EFHC1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV64137143; called by muse, mutect2, varscan2
- EGR2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs1411119456, COSV54346023, COSV54348081; called by muse, varscan2
- EHBP1 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1299192365, COSV50428756; called by muse, mutect2, varscan2
- EIF3L | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV67739884; called by muse, mutect2, varscan2
- ELMO2 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV51685056; called by muse, mutect2, varscan2
- ELOVL3 | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV64174771; called by muse, mutect2, varscan2
- ENTHD1 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1310435397, COSV57323032; called by muse, mutect2, varscan2
- EOMES | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767871834, COSV55413919; called by muse, mutect2, varscan2
- EPC2 | c.1281T>A p.D427E | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99309619; called by muse, mutect2, varscan2
- EPHA4 | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.399); catalogued as rs752075336, COSV56039692; called by muse, mutect2, varscan2
- ERAP2 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369871017, COSV65940766; called by muse, mutect2, varscan2
- ERN2 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs139816512; called by muse, mutect2, varscan2
- ETV1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 89/356 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV54140522, COSV54147776; called by muse, mutect2, varscan2
- EXD3 | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59810777; called by muse, mutect2
- EYA2 | c.416-1G>A p.X139_splice | Splice Site (SNP) | VAF 22/44 reads (50%) | catalogued as COSV57948138; called by muse, varscan2
- EZHIP | c.1067T>A p.L356H | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.896); catalogued as rs372310167, COSV100539742; called by muse, mutect2, varscan2
- F13A1 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53563293; called by muse, mutect2, varscan2
- F5 | c.1614G>A p.R538= | Splice Region (SNP) | VAF 31/103 reads (30%) | catalogued as COSV63122211; called by muse, mutect2, varscan2
- FAAH2 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV66510231; called by muse, mutect2, varscan2
- FAM114A1 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.059); catalogued as COSV62674075; called by muse, mutect2, varscan2
- FAM124B | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1280865122, COSV54739336; called by muse, mutect2, varscan2
- FAM170A | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58926356; called by muse, mutect2, varscan2
- FAM227B | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54815793; called by muse, mutect2, varscan2
- FANCD2 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 47/413 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV55036408; called by muse, mutect2, varscan2
- FAT3 | c.6376G>A p.D2126N | Missense Mutation (SNP) | VAF 169/676 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.397); catalogued as COSV53148743; called by muse, mutect2, varscan2
- FAT4 | c.8060G>A p.R2687Q | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs777764521, COSV58675395; called by muse, mutect2, varscan2
- FATE1 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.058); catalogued as COSV64849181; called by muse, mutect2, varscan2
- FBLN2 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV55488449; called by muse, mutect2
- FBXL19 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1400290303, COSV57944942; called by muse, mutect2, varscan2
- FCRL3 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs138227125; called by muse, mutect2, varscan2
- FILIP1 | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.392); catalogued as COSV52729748; called by muse, mutect2, varscan2
- FLNB | c.2088G>A p.M696I | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV55888218; called by muse, mutect2, varscan2
- FLT3 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54058304; called by muse, mutect2, varscan2
- FNBP1L | c.1693C>T p.L565F (on ENST00000271234 / NM_001164473.2; = p.L507F on NM_017737.5) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV53095358; called by muse, mutect2, varscan2
- FOSL2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV53105093; called by muse, mutect2, varscan2
- FOXI1 | c.927T>G p.S309R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs202009815, COSV60389423; called by muse, mutect2, varscan2
- FTH1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV56446148; called by muse, mutect2, varscan2
- GABPB2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV64461223; called by muse, mutect2, varscan2
- GABRA2 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as rs1428045491, COSV100734734, COSV62915909; called by muse, mutect2, varscan2
- GABRA3 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV64798831, COSV64804398; called by muse, mutect2, varscan2
- GCFC2 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1413999402, COSV58082434; called by muse, mutect2, varscan2
- GGA1 | c.1034C>G p.A345G | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57331132; called by muse, mutect2, varscan2
- GHRHR | c.176G>A p.W59* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV58197473; called by muse, mutect2
- GIMAP4 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55433846; called by muse, mutect2, varscan2
- GIMAP6 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.322); catalogued as COSV61034223; called by muse, mutect2, varscan2
- GIMAP6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV61033983; called by mutect2, varscan2
- GNAS | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV58341835; called by muse, mutect2, varscan2
- GNB3 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV57529779; called by muse, mutect2, varscan2
- GPKOW | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV50244127, COSV99332551; called by muse, mutect2, varscan2
- GPR63 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV57742556; called by muse, mutect2, varscan2
- GPR68 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.933); catalogued as rs1414869163, COSV53177003; called by muse, mutect2, varscan2
- GPRC6A | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV59952621; called by muse, mutect2, varscan2
- GPX6 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV62658560; called by muse, mutect2, varscan2
- GPX6 | c.260A>C p.E87A | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.699); catalogued as COSV62658569; called by muse, mutect2, varscan2
- GRAP2 | c.618A>C p.Q206H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59996359; called by muse, mutect2, varscan2
- GRIN2A | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs560839364, COSV58047616; called by muse, mutect2, varscan2
- GRM7 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63157570; called by muse, mutect2, varscan2
- GSDMB | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV58781842; called by muse, mutect2, varscan2
- GUCA1C | c.277T>A p.L93I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1559841782, COSV53751094, COSV99659718; called by muse, mutect2, varscan2
- GYS2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV53926463; called by muse, mutect2, varscan2
- HDAC4 | c.2185A>T p.N729Y | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61871702; called by muse, mutect2, varscan2
- HDAC9 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs867608188, COSV67780235; called by muse, mutect2, varscan2
- HERC2 | c.10945G>A p.E3649K | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55339348; called by muse, mutect2, varscan2
- HIPK2 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); catalogued as COSV61230849; called by muse, mutect2, varscan2
- HLA-DMA | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 187/374 reads (50%) | catalogued as COSV66385983; called by muse, mutect2, varscan2
- HMCN1 | c.4169C>T p.P1390L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54922652; called by muse, mutect2, varscan2
- HMGB4 | c.165T>G p.H55Q | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV53938881; called by muse, mutect2, varscan2
- HOXD4 | c.567C>A p.H189Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60460445; called by muse, mutect2, varscan2
- HPSE | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV60987967; called by muse, mutect2, varscan2
- HS3ST4 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV58824675; called by muse, mutect2, varscan2
- HYDIN | c.6305G>A p.G2102E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.025); catalogued as COSV59264638; called by muse, mutect2, varscan2
- HYDIN | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58556597; called by muse, mutect2, varscan2
- ICAM2 | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs773489521, COSV56743218; called by muse, mutect2, varscan2
- IFT57 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV52710984; called by muse, mutect2, varscan2
- IGHV1-24 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 98/352 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs781997774; called by muse, mutect2, varscan2
- ING3 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV59951729; called by muse, mutect2, varscan2
- ITGA1 | c.2050C>T p.Q684* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV50890215; called by mutect2, varscan2
- ITGA11 | c.3182G>A p.S1061N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV100242401, COSV59880282; called by muse, mutect2, varscan2
- ITGA2B | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV52233902; called by muse, mutect2, varscan2
- ITGB3 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as rs150951945; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV59825759; called by muse, mutect2, varscan2
- KANSL1 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV52271836; called by muse, mutect2, varscan2
- KASH5 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766710152, COSV71358216; called by muse, mutect2, varscan2
- KAT14 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV66608632; called by muse, mutect2, varscan2
- KBTBD6 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs867793426, COSV65270849; called by muse, mutect2, varscan2
- KCNA5 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV52905514; called by muse, mutect2, varscan2
- KCNA6 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99768257; called by muse, mutect2, varscan2
- KCND2 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs767027587, COSV58577133; called by muse, mutect2, varscan2
- KCNH2 | c.1944C>T p.G648= | Splice Region (SNP) | VAF 48/171 reads (28%) | catalogued as COSV51213723; called by muse, mutect2, varscan2
- KCNH5 | c.2245G>A p.G749R | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs758320399, COSV100526189, COSV59769497; called by muse, mutect2, varscan2
- KCNQ5 | c.1723C>T p.L575F | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.449); catalogued as COSV59658996, COSV59673409; called by muse, mutect2, varscan2
- KCNU1 | c.1171T>C p.S391P | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.454); catalogued as COSV67758369; called by muse, mutect2, varscan2
- KCTD13 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58161003; called by muse, mutect2, varscan2
- KHSRP | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as COSV67920088; called by muse, mutect2, varscan2
- KIAA0100 | c.6341C>T p.S2114F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV56382802; called by muse, mutect2, varscan2
- KIAA1217 | c.355-1G>A p.X119_splice | Splice Site (SNP) | VAF 26/107 reads (24%) | catalogued as COSV64609864; called by muse, mutect2, varscan2
- KIF26A | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs772147308, COSV59468723; called by muse, mutect2, varscan2
- KLC1 | c.482T>C p.I161T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.224); catalogued as COSV55809856; called by muse, varscan2
- KLF10 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53436201; called by muse, mutect2, varscan2
- KMT2C | c.14545C>T p.H4849Y | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51474974; called by muse, mutect2, varscan2
- KNDC1 | c.4210C>T p.L1404F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs1334464772, COSV58842696; called by muse, mutect2, varscan2
- KRT25 | c.705C>G p.N235K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV100379945; called by muse, mutect2, varscan2
- KRT25 | c.704A>T p.N235I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100379946; called by muse, mutect2, varscan2
- KRT36 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752593807, COSV60204210; called by muse, mutect2, varscan2
- KRT5 | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs767692987, COSV52859277; called by muse, mutect2, varscan2
- KRTAP10-8 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as rs781983764, COSV58165851; called by muse, mutect2, varscan2
- KSR2 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 142/589 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.724); catalogued as COSV60387624; called by muse, mutect2, varscan2
- LAMA3 | c.5650C>T p.H1884Y (on ENST00000313654 / NM_198129.4; = p.H275Y on NM_000227.6) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV52539399, COSV99334904; called by muse, mutect2, varscan2
- LDHA | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV57041577; called by muse, mutect2, varscan2
- LGALS9B | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV60865564; called by muse, mutect2, varscan2
- LIMK2 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV59183518; called by muse, mutect2, varscan2
- LIPI | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60709984, COSV60710287, COSV60712383; called by muse, mutect2, varscan2
- LRR1 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749817002, COSV53564124; called by muse, mutect2, varscan2
- LRRC3 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as rs200023400, COSV52399864; called by muse, mutect2, varscan2
- LRRC58 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV55230798; called by muse, mutect2
- LRRC66 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV58635591; called by muse, mutect2, varscan2
- LRRC66 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV58635602; called by muse, mutect2, varscan2
- LRRIQ1 | c.3700C>T p.H1234Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1321601759, COSV67830042; called by muse, mutect2, varscan2
- LRTM2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54565887; called by muse, mutect2, varscan2
- LTF | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs1160569191, COSV51610481; called by muse, mutect2, varscan2
- MAML2 | c.3140T>C p.L1047P | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.804); catalogued as COSV73264276; called by muse, mutect2, varscan2
- MAP3K9 | c.2563G>A p.D855N (on ENST00000554752 / NM_001284230.1; = p.D869N on NM_033141.4) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs771607431, COSV67121452, COSV67122292; called by muse, mutect2, varscan2
- MAP7 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs770928694, COSV63421698; called by muse, mutect2, varscan2
- MARCHF1 | c.224C>T p.S75F (on ENST00000274056; = p.S58F on NM_017923.4) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV56823721; called by muse, mutect2, varscan2
- MAST2 | c.3322C>T p.H1108Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.613); catalogued as COSV63620253; called by muse, mutect2, varscan2
- MECOM | c.602C>T p.S201L (on ENST00000468789 / NM_001105078.4; = p.S389L on NM_004991.4) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52960794; called by muse, mutect2, varscan2
- MEOX1 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59356854; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, mutect2, varscan2
- MGAM | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 90/358 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868995180, COSV72074117; called by muse, mutect2, varscan2
- MKRN3 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.291); catalogued as COSV58809701; called by muse, mutect2, varscan2
- MMP25 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.474); catalogued as COSV60680539; called by muse, mutect2, varscan2
- MPPED1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV61988349; called by muse, mutect2, varscan2
- MS4A4A | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.109); catalogued as COSV59700284; called by muse, mutect2, varscan2
- MSRB3 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867671100, COSV57590583; called by muse, mutect2, varscan2
- MUC13 | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60699977, COSV60701525; called by muse, mutect2, varscan2
- MUC13 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.387); catalogued as rs1351397481, COSV60700619; called by muse, mutect2, varscan2
- MUC16 | c.33560C>T p.S11187F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV67481005; called by muse, mutect2, varscan2
- MUC16 | c.31660C>T p.P10554S | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.062); catalogued as rs1489638777, COSV67447282; called by muse, mutect2, varscan2
- MUC16 | c.16741C>T p.P5581S | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.053); catalogued as COSV67447377; called by muse, mutect2, varscan2
- MUC17 | c.11128G>A p.E3710K | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs370058081; called by muse, mutect2, varscan2
- MXRA5 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV54243531; called by muse, mutect2, varscan2
- MYBBP1A | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1000797393, COSV54600941; called by muse, mutect2, varscan2
- MYCT1 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV65891728; called by muse, mutect2, varscan2
- MYH13 | c.3271C>T p.L1091F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs763892093, COSV52836676; called by muse, mutect2, varscan2
- MYH2 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55433645; called by muse, mutect2, varscan2
- MYO18A | c.1139T>G p.V380G | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV62870688; called by muse, mutect2, varscan2
- MYO5C | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs371946722; called by muse, mutect2, varscan2
- MYT1 | c.1405A>T p.K469* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV60510318; called by muse, mutect2, varscan2
- NALCN | c.1747C>T p.H583Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51952365; called by muse, mutect2, varscan2
- NF2 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs1347744596, COSV58527607; called by muse, mutect2, varscan2
- NIBAN1 | c.1828G>A p.G610S | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100836405; called by muse, mutect2, varscan2
- NIT2 | c.779T>A p.V260D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV101237096; called by muse, mutect2, varscan2
- NLRP13 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 43/75 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); catalogued as rs1459936417, COSV61619938; called by muse, mutect2, varscan2
- NLRP14 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV100204454, COSV55070057; called by muse, mutect2, varscan2
- NLRP4 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as rs1175246779, COSV56709262, COSV56719853; called by muse, mutect2, varscan2
- NOB1 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV52062547; called by muse, mutect2, varscan2
- NPR3 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as rs1322446173, COSV54091034; called by muse, mutect2, varscan2
- NRDE2 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV62964121, COSV62964418; called by muse, mutect2
- NRG3 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV64562880; called by muse, mutect2, varscan2
- NRXN2 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55459527; called by muse, mutect2, varscan2
- NSD1 | c.3394G>A p.G1132R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs570278983, COSV100728597, COSV61786245; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- NSD1 | c.3395G>A p.G1132E | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.062); catalogued as COSV100729226; called by muse, mutect2
- NUMA1 | c.4517A>G p.E1506G | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61188625; called by muse, mutect2, varscan2
- NXF3 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67704569; called by muse, mutect2, varscan2
- OBSL1 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV54725983; called by muse, mutect2, varscan2
- OLFM1 | c.328G>T p.V110F (on ENST00000371793 / NM_001282611.2; = p.V92F on NM_006334.4) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as rs751893069, COSV52963118; called by muse, mutect2, varscan2
- OR10A3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as rs867656808, COSV62459900; called by muse, mutect2, varscan2
- OR10J5 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs146863607, COSV58385033; called by muse, mutect2, varscan2
- OR2A5 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 34/131 reads (26%) | catalogued as COSV68738960; called by muse, mutect2, varscan2
- OR2F2 | c.888G>C p.E296D | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as rs1411142469, COSV68833124; called by muse, mutect2, varscan2
- OR2G2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs1434578514, COSV60739436; called by muse, mutect2, varscan2
- OR2M7 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58739969; called by muse, mutect2, varscan2
- OR2W1 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65851776; called by muse, mutect2, varscan2
- OR4C12 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV58860061, COSV58860670; called by muse, mutect2, varscan2
- OR4K2 | c.239A>T p.K80M | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53850802; called by muse, mutect2, varscan2
- OR52A1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs199986389; called by muse, mutect2, varscan2
- OR52L1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs982635202, COSV59986572; called by muse, mutect2, varscan2
- OR5H14 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs773842801, COSV71193659; called by muse, mutect2, varscan2
- OR5L1 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV61732697, COSV61733111, COSV61733957; called by muse, mutect2, varscan2
- OR6C65 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 97/265 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.924); catalogued as rs1213339398, COSV101110170, COSV101110211; called by muse, mutect2, varscan2
- OR7G1 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53316950, COSV53318851; called by muse, mutect2, varscan2
- OR8D4 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs867554307, COSV58429605; called by muse, mutect2, varscan2
- OR8H3 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57910336; called by muse, mutect2, varscan2
- ORC6 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV54480153; called by muse, mutect2, varscan2
- OSBPL1A | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs144234125; called by muse, mutect2, varscan2
- OSR1 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs867715743, COSV55346056; called by muse, mutect2, varscan2
- OTUD7B | c.2192C>T p.P731L | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64917129; called by muse, mutect2, varscan2
- OVOL2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53861402; called by muse, mutect2, varscan2
- P2RX5 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56591873; called by muse, mutect2, varscan2
- P2RX7 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 214/804 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55856631; called by muse, mutect2, varscan2
- PADI4 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV64924577; called by muse, mutect2, varscan2
- PAK5 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV62030879; called by muse, mutect2, varscan2
- PAM | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV57216930; called by muse, mutect2, varscan2
- PANX2 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50304550; called by muse, mutect2, varscan2
- PAPPA2 | c.1209C>A p.C403* | Nonsense Mutation (SNP) | VAF 25/121 reads (21%) | catalogued as rs759651747, COSV62776339; called by muse, mutect2, varscan2
- PASD1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as COSV64856595, COSV64858488; called by muse, mutect2, varscan2
- PCDH18 | c.2725G>A p.G909R | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as COSV61268377; called by muse, mutect2, varscan2
- PCDHA10 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.661); catalogued as rs782472888, COSV56529368; called by muse, mutect2, varscan2
- PCDHA6 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV100971214, COSV65343389; called by muse, mutect2, varscan2
- PCDHB11 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.336); catalogued as rs1322914499, COSV61313487; called by muse, varscan2
- PCDHB16 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs782772782, COSV53367448, COSV99500877; called by muse, mutect2, varscan2
- PCLO | c.1676G>A p.S559N | Missense Mutation (SNP) | VAF 151/515 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV61652789; called by muse, mutect2, varscan2
- PDCD11 | c.4167C>A p.N1389K | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs764921702, COSV63934692; called by muse, mutect2, varscan2
- PDE11A | c.356A>T p.K119I | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV53702582; called by muse, mutect2, varscan2
- PDE4DIP | c.4480G>A p.E1494K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV57715371; called by muse, mutect2, varscan2
- PDE6B | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as rs140444984; called by muse, mutect2, varscan2
- PDHA2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs267600306, COSV54776945; called by muse, mutect2, varscan2
- PDZD8 | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 26/102 reads (25%) | catalogued as COSV57823680; called by muse, mutect2, varscan2
- PEG3 | c.2119C>T p.H707Y | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.858); catalogued as rs775898856, COSV55627247; called by muse, mutect2, varscan2
- PGAP1 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61324318, COSV61328176; called by muse, mutect2, varscan2
- PGGHG | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV66888444; called by muse, mutect2, varscan2
- PHF2 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as rs372646548; called by muse, mutect2, varscan2
- PHLDB2 | c.2248G>A p.E750K (on ENST00000393925 / NM_001134439.2; = p.E707K on NM_145753.2) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV67307958; called by mutect2, varscan2
- PIGF | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV53231963; called by muse, mutect2, varscan2
- PIP4P1 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV51658430; called by muse, mutect2, varscan2
- PKDREJ | c.3505C>T p.P1169S | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV53551401; called by muse, mutect2, varscan2
- PKHD1L1 | c.2738G>A p.G913E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs866551110, COSV65738761, COSV65751132; called by muse, mutect2, varscan2
- PKHD1L1 | c.5653C>T p.P1885S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65748599; called by muse, mutect2
- PLEKHG7 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as rs1022335352, COSV67338085, COSV67338161; called by muse, mutect2, varscan2
- PLEKHO2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs374093329; called by muse, mutect2, varscan2
- PLXNA4 | c.3380C>T p.S1127F | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58146915; called by muse, mutect2, varscan2
- PMS1 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1187460357, COSV59718810; called by muse, mutect2, varscan2
- POF1B | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53137796; called by muse, mutect2, varscan2
- POLQ | c.4040C>T p.T1347I | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV51757569; called by muse, mutect2, varscan2
- PPEF2 | c.1957A>G p.N653D | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.994); catalogued as COSV54424823; called by muse, mutect2, varscan2
- PPFIA1 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV54138560; called by muse, mutect2, varscan2
- PPP2R5C | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58270148, COSV58274564; called by muse, mutect2, varscan2
- PRAM1 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs530402541, COSV55314734; called by muse, mutect2, varscan2
- PRDX6 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61165973; called by muse, mutect2, varscan2
- PREX2 | c.1599G>A p.M533I | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV55788538, COSV99909628; called by muse, mutect2, varscan2
- PROM2 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV58299776; called by muse, mutect2
- PRPSAP1 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61212107; called by muse, mutect2, varscan2
- PSG4 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756543425, COSV54938352; called by muse, mutect2, varscan2
- PTCHD4 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59785782, COSV59791733; called by muse, mutect2, varscan2
- PTPN22 | c.1048G>A p.E350K (on ENST00000359785 / NM_001193431.2; = p.E295K on NM_012411.5) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV63084299, COSV63085971; called by muse, mutect2, varscan2
- PTPRZ1 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66438322; called by muse, mutect2, varscan2
- PXDNL | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177849906, COSV62480262; called by muse, mutect2, varscan2
- RAB29 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 122/422 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV52521780; called by muse, mutect2, varscan2
- RADX | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV100998703; called by muse, mutect2, varscan2
- RASGRP1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60366593; called by muse, mutect2, varscan2
- RBBP6 | c.4693C>T p.P1565S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV60507291; called by muse, mutect2, varscan2
- RBL1 | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1168350319, COSV60331762; called by muse, mutect2, varscan2
- RBM11 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs775462880, COSV68748261; called by muse, mutect2, varscan2
- RET | c.74-1G>A p.X25_splice | Splice Site (SNP) | VAF 27/74 reads (36%) | catalogued as COSV60702406; called by muse, mutect2, varscan2
- RFX3 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV56517856, COSV56521340; called by muse, mutect2, varscan2
- RGS9 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV99287243; called by muse, mutect2, varscan2
- RING1 | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 169/355 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV63002791; called by muse, mutect2, varscan2
- RIPPLY3 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV61566593; called by muse, mutect2, varscan2
- RIT2 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV56304827; called by muse, mutect2, varscan2
- RNASEL | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV62377496; called by muse, mutect2, varscan2
- RNF112 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV71978780; called by muse, mutect2
- RNF130 | c.635G>A p.W212* | Nonsense Mutation (SNP) | VAF 48/145 reads (33%) | catalogued as COSV56152305; called by muse, mutect2, varscan2
- RNF149 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.357); catalogued as COSV54864893; called by muse, mutect2
- ROBO3 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67301923; called by muse, mutect2
- ROR2 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV65220453, COSV65221961; called by muse, mutect2, varscan2
- RSAD2 | c.774T>G p.C258W | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV65908688; called by muse, mutect2, varscan2
- RUNX1T1 | c.1676A>T p.Q559L (on ENST00000265814 / NM_001198628.1; = p.Q532L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV56156242; called by muse, mutect2, varscan2
- RYR2 | c.4816G>A p.V1606I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV63701481; called by muse, mutect2, varscan2
- RYR2 | c.14528G>A p.R4843Q | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63676917; called by muse, mutect2, varscan2
- SAMD7 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59420243; called by muse, mutect2, varscan2
- SAMD9 | c.3749T>C p.L1250P | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV101180268; called by muse, mutect2, varscan2
- SAMD9 | c.3748C>T p.L1250F | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs980016258, COSV101180269; called by muse, mutect2, varscan2
- SCARA5 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV61571237, COSV61573282; called by muse, mutect2, varscan2
- SCN2A | c.6010A>G p.K2004E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.079); catalogued as rs769884541, COSV51849766; called by muse, mutect2, varscan2
- SCN3A | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV51818071; called by muse, mutect2, varscan2
- SCN4A | c.4885C>T p.P1629S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV71126440; called by muse, mutect2, varscan2
- SERPINA12 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs780070277, COSV57944498; called by muse, mutect2, varscan2
- SERPINA7 | c.875G>A p.W292* | Nonsense Mutation (SNP) | VAF 80/165 reads (48%) | catalogued as rs902678899, COSV59665870; called by muse, mutect2, varscan2
- SF3A1 | c.398A>C p.Q133P | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.84); catalogued as COSV53170309; called by muse, mutect2, varscan2
- SGMS1 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as COSV62371649; called by muse, mutect2, varscan2
- SI | c.4648G>A p.A1550T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs766815320, COSV52291038; called by muse, mutect2, varscan2
- SIGLEC8 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.085); catalogued as COSV58474972; called by muse, mutect2, varscan2
- SIPA1L3 | c.4382G>A p.R1461K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55920402; called by muse, mutect2, varscan2
- SIRPB1 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.045); catalogued as COSV53539952, COSV99498463; called by muse, mutect2, varscan2
- SLC13A1 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV52009408, COSV52014679; called by muse, mutect2, varscan2
- SLC13A5 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV53424278; called by muse, mutect2, varscan2
- SLC22A4 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52359365; called by muse, mutect2, varscan2
- SLC22A6 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV64560659; called by muse, mutect2, varscan2
- SLC25A17 | c.578T>A p.L193H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as COSV54352187; called by muse, mutect2, varscan2
- SLC25A23 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778473826, COSV51194210; called by muse, mutect2, varscan2
- SLC25A6 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs1355373029, COSV100452189, COSV58432626; called by muse, mutect2, varscan2
- SLC6A1 | c.1656G>A p.M552I | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as rs1429079016, COSV55117387; called by muse, mutect2, varscan2
- SLC8A3 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63520960, COSV63524605; called by muse, mutect2, varscan2
- SLC9C1 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV59885939, COSV59890859; called by muse, mutect2
- SLCO1B3 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1408642500, COSV53937278, COSV53942791; called by muse, mutect2, varscan2
- SLIT2 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.887); catalogued as COSV56585218; called by muse, mutect2, varscan2
- SLX4 | c.4028C>T p.P1343L | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1341974917, COSV53566570, COSV99567465; called by muse, mutect2, varscan2
- SMURF2 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52317873; called by muse, mutect2, varscan2
- SNCAIP | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV54416651; called by muse, mutect2, varscan2
- SPAG16 | c.1263G>A p.W421* | Nonsense Mutation (SNP) | VAF 24/111 reads (22%) | catalogued as rs375753147; called by muse, mutect2, varscan2
- SPAM1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56144132; called by muse, mutect2, varscan2
- SPEF2 | c.4486G>A p.D1496N | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs758237434, COSV57428817; called by muse, mutect2, varscan2
- SPEN | c.6241C>T p.R2081* | Nonsense Mutation (SNP) | VAF 21/148 reads (14%) | catalogued as COSV65360117; called by muse, mutect2, varscan2
- SPHKAP | c.3686G>A p.R1229Q | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754167845, COSV60871584; called by muse, mutect2, varscan2
- SPPL2C | c.1951C>T p.H651Y | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as rs370606755, COSV61293293; called by muse, mutect2, varscan2
- SPRR1B | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV61067938; called by muse, mutect2, varscan2
- SPRR1B | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as rs750358682, COSV61067945; called by muse, mutect2, varscan2
- SPRY1 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59338890; called by muse, mutect2, varscan2
- SSTR5 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53511208; called by muse, mutect2, varscan2
- STIM2 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52841675, COSV99403167; called by muse, mutect2, varscan2
- STK10 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51576875, COSV51578170; called by muse, mutect2, varscan2
- STPG1 | c.962C>T p.S321F (on ENST00000337248 / NM_001199013.2; = p.S274F on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50221712; called by muse, mutect2
- STRIP1 | c.1993C>T p.L665F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV63930875; called by muse, mutect2, varscan2
- SUSD2 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs369875223; called by muse, mutect2, varscan2
- SYCP1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV65699813; called by muse, mutect2, varscan2
- SYCP1 | c.2664T>G p.F888L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.34); catalogued as COSV65699817, COSV65700540, COSV65701481; called by muse, mutect2, varscan2
- TAP1 | c.2134G>T p.A712S | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62755263; called by muse, mutect2, varscan2
- TAS1R1 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 51/170 reads (30%) | catalogued as COSV60229383; called by muse, mutect2, varscan2
- TAS1R2 | c.1591+1G>A p.X531_splice | Splice Site (SNP) | VAF 16/118 reads (14%) | catalogued as rs761814490, COSV64746173; called by muse, mutect2, varscan2
- TBC1D14 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV68986711; called by muse, mutect2, varscan2
- TBC1D9 | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV71308157; called by muse, mutect2, varscan2
- TBCK | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56759661; called by muse, mutect2, varscan2
- TCEAL6 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.616); catalogued as COSV65654120; called by muse, mutect2, varscan2
- TECPR1 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV65784409; called by muse, varscan2
- TENM3 | c.2306G>A p.R769K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV69314583; called by muse, mutect2, varscan2
- TG | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143578780, COSV55069694; called by muse, mutect2, varscan2
- TG | c.7279G>A p.E2427K | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV55087563; called by muse, mutect2, varscan2
- THBS1 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV52954188; called by muse, mutect2, varscan2
- THSD7B | c.2498G>A p.R833K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV55716333; called by muse, mutect2, varscan2
- TIMM8A | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 82/131 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV58122371; called by muse, mutect2, varscan2
- TIMP3 | c.571T>A p.Y191N | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV56665703; called by muse, mutect2, varscan2
- TJAP1 | c.848C>A p.P283H (on ENST00000372445 / NM_001146016.1; = p.P273H on NM_080604.3) | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52502688; called by muse, mutect2, varscan2
- TMC5 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 93/268 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs369805960; called by muse, mutect2, varscan2
- TMEM132D | c.1877G>A p.G626D | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67161516; called by muse, mutect2, varscan2
- TMEM175 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as rs766017281, COSV53277664; called by muse, mutect2, varscan2
- TMEM266 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV66380726; called by muse, mutect2, varscan2
- TMEM38B | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as rs1475715558, COSV65949654; called by muse, mutect2, varscan2
- TMEM63C | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100029484, COSV53606407; called by muse, mutect2, varscan2
- TMPRSS11B | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV60292519; called by muse, mutect2, varscan2
- TMPRSS3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.76); catalogued as rs781420452, COSV52305521; called by muse, mutect2, varscan2
- TMX3 | c.701T>G p.M234R | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV55186634; called by muse, mutect2, varscan2
- TOGARAM2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as COSV65421541, COSV65422924; called by muse, mutect2, varscan2
- TOP2B | c.1121C>T p.P374L (on ENST00000264331 / NM_001330700.2; = p.P369L on NM_001068.3) | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV51975096; called by muse, mutect2, varscan2
- TRPC6 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.048); catalogued as rs750615513, COSV60258416; called by muse, mutect2, varscan2
- TRRAP | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs147405090, COSV62839126, COSV62849075; called by muse, mutect2, varscan2
- TSPAN2 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753573127, COSV65690375; called by muse, mutect2, varscan2
- TSPY2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.53); catalogued as COSV100289194; called by muse, mutect2, varscan2
- TTLL2 | c.849A>T p.E283D | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.712); catalogued as COSV53445059; called by muse, mutect2, varscan2
- TTLL7 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53087175; called by muse, mutect2, varscan2
- TTN | c.85538C>T p.P28513L (on ENST00000591111; = p.P21089L on NM_003319.4) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | PolyPhen probably damaging (0.999); catalogued as COSV100628996, COSV60220063; called by muse, mutect2, varscan2
- TTN | c.10885C>T p.P3629S (on ENST00000591111; = p.P3583S on NM_003319.4) | Missense Mutation (SNP) | VAF 65/259 reads (25%) | catalogued as rs970485392, COSV100615432; called by muse, mutect2, varscan2
- TTPA | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99478532; called by muse, mutect2, varscan2
- UBQLNL | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV66493031; called by muse, mutect2, varscan2
- UBTD2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs376318802; called by muse, mutect2, varscan2
- UGT2B11 | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as COSV71422936; called by muse, mutect2, varscan2
- UGT2B17 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs1183093527, COSV58502234; called by muse, mutect2, varscan2
- UGT2B17 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV58502242; called by muse, mutect2, varscan2
- ULK4 | c.127A>T p.I43L | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as COSV57216345; called by muse, mutect2, varscan2
- UNC79 | c.1909C>T p.P637S (on ENST00000393151 / NM_001346218.2; = p.P460S on NM_020818.5) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56400746; called by muse, mutect2, varscan2
- USF3 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.197); catalogued as COSV57075544; called by muse, mutect2, varscan2
- USH2A | c.4825G>A p.E1609K | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as COSV56366614; called by muse, mutect2, varscan2
- USH2A | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs373190681, CM149915, COSV56437947; called by muse, mutect2, varscan2
- USP16 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421977168, COSV57626973; called by muse, mutect2, varscan2
- USP26 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.65); PolyPhen benign (0.155); catalogued as COSV63707997, COSV63709309; called by muse, mutect2, varscan2
- VAV2 | c.1456G>T p.G486* (on ENST00000371850 / NM_001134398.2; = p.G476* on NM_003371.4) | Nonsense Mutation (SNP) | VAF 16/26 reads (62%) | catalogued as COSV64083867; called by muse, mutect2, varscan2
- VCX | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs775158454, COSV58233316; called by muse, varscan2
- VPS35L | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as COSV51987736; called by muse, mutect2, varscan2
- WEE2 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66879698; called by muse, mutect2, varscan2
- WIF1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54134047; called by muse, mutect2, varscan2
- XIRP1 | c.4738G>A p.D1580N | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as COSV61139975; called by muse, mutect2, varscan2
- YTHDC1 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as rs199646486, COSV60011469; called by muse, mutect2, varscan2
- ZBBX | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV56796236; called by muse, mutect2, varscan2
- ZBED9 | c.3437G>A p.R1146K | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); catalogued as rs533040091, COSV71729467; called by muse, mutect2, varscan2
- ZBTB32 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52891731; called by muse, mutect2, varscan2
- ZBTB40 | c.3563A>G p.Q1188R | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs769980225, COSV65146056; called by muse, mutect2, varscan2
- ZBTB7B | c.583C>T p.R195W (on ENST00000292176; = p.R229W on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs367725892; called by muse, mutect2, varscan2
- ZDBF2 | c.4513C>T p.P1505S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.234); catalogued as COSV65623450; called by muse, mutect2, varscan2
- ZFHX4 | c.2327C>T p.T776I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51478527; called by muse, mutect2, varscan2
- ZFP69B | c.1486A>G p.I496V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV64315863; called by muse, mutect2, varscan2
- ZFPM2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV65874917; called by muse, mutect2, varscan2
- ZNF239 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as rs200148264; called by muse, mutect2, varscan2
- ZNF423 | c.2302C>T p.R768C (on ENST00000563137 / NM_001379286.1; = p.R760C on NM_015069.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs764927116, COSV52183452; called by muse, mutect2, varscan2
- ZSWIM4 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as COSV54324407; called by muse, mutect2, varscan2
- CREB3L3 | c.1042_1048del p.E348Lfs*62 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- DNAH3 | c.1244_1245del p.R415Qfs*14 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | called by muse*, mutect2, varscan2*
- GPR179 | c.3742G>A p.E1248K (on ENST00000621958; = p.E1247K on NM_001004334.4) | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR179 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by muse, mutect2
- IGKV2-30 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- KDM2B | c.615_616insTCCAG p.H206Sfs*4 | Frame Shift Ins (INS) | VAF 24/111 reads (22%) | called by mutect2, pindel, varscan2
- KMT2A | c.2989_3004del p.S997Pfs*5 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- TPTE | c.1582C>T p.P528S (on ENST00000618007 / NM_199261.4; = p.P510S on NM_199259.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- USP6 | c.1998G>A p.W666* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- ZFX | c.755dup p.V253Gfs*5 | Frame Shift Ins (INS) | VAF 44/86 reads (51%) | called by mutect2, pindel, varscan2
- ZNF26 | c.636T>G p.S212R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AC005324.2 | c.798G>A p.K266= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV60887694; called by muse, mutect2, varscan2
- AC104389.6 | c.453C>T p.S151= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV57964162; called by muse, mutect2, varscan2
- ACTC1 | c.849C>T p.S283= | Silent (SNP) | VAF 28/194 reads (14%) | called by muse, varscan2
- ADAMDEC1 | c.18C>T p.S6= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs764795387, COSV56476598; called by muse, mutect2, varscan2
- ADD2 | c.345C>T p.I115= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV52466587; called by muse, mutect2, varscan2
- ADGRA2 | c.1602C>T p.I534= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1454289034, COSV59445738; called by muse, mutect2, varscan2
- ADGRG1 | c.192C>T p.A64= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV65636246; called by muse, mutect2, varscan2
- ADH1A | c.585C>T p.T195= | Silent (SNP) | VAF 75/218 reads (34%) | catalogued as COSV52925735, COSV52926836; called by muse, varscan2
- AJAP1 | c.267C>T p.I89= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV65452486; called by muse, mutect2, varscan2
- ALDH7A1 | c.880C>T p.L294= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV68629746; called by muse, mutect2
- ALPK3 | c.5106G>A p.Q1702= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99360999; called by muse, mutect2, varscan2
- ANK3 | c.9351C>T p.I3117= | Silent (SNP) | VAF 44/171 reads (26%) | catalogued as COSV55045291; called by muse, mutect2, varscan2
- ANKMY1 | c.1483T>C p.L495= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV56038156; called by muse, mutect2, varscan2
- AOX1 | c.468C>T p.P156= | Silent (SNP) | VAF 53/194 reads (27%) | catalogued as COSV65982959; called by muse, mutect2, varscan2
- APLP2 | c.2184C>T p.I728= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs756716777, COSV53842748; called by muse, mutect2, varscan2
- ARMC4 | c.351G>A p.G117= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV53467146; called by muse, mutect2, varscan2
- ARSH | c.1515C>T p.S505= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs780794500, COSV66963578; called by muse, varscan2
- ASB5 | c.312C>T p.V104= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV56672880; called by muse, mutect2, varscan2
- ATAD1 | c.805C>T p.L269= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as COSV57757880; called by muse, mutect2, varscan2
- ATG13 | c.1113C>T p.V371= (on ENST00000359513 / NM_001346321.1; = p.V334= on NM_014741.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV56321145; called by muse, mutect2, varscan2
- ATP1B4 | c.153G>A p.S51= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs145284908, COSV54313477, COSV99486228; called by muse, mutect2, varscan2
- ATXN2 | c.1872C>T p.S624= (on ENST00000550104; = p.S464= on NM_002973.4) | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs957266513, COSV101112778; called by muse, mutect2, varscan2
- B3GAT1 | c.48C>T p.P16= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs979539228, COSV56999390; called by muse, mutect2, varscan2
- BLM | c.3900C>T p.S1300= | Silent (SNP) | VAF 106/431 reads (25%) | catalogued as rs769564626, COSV61925889; called by muse, mutect2, varscan2
- BTN2A1 | c.381C>T p.F127= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV57005326; called by muse, mutect2, varscan2
- C7orf61 | c.510C>T p.R170= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV60093207; called by muse, mutect2, varscan2
- CAMK2G | c.48C>T p.L16= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV59484011; called by muse, mutect2, varscan2
- CAPZA3 | c.75G>A p.G25= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV56848350; called by muse, mutect2, varscan2
- CAPZA3 | c.327C>T p.I109= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs780507786, COSV56852315; called by muse, mutect2, varscan2
- CARMIL3 | c.1005C>T p.S335= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV57727643; called by muse, mutect2, varscan2
- CBLC | c.231G>A p.G77= | Silent (SNP) | VAF 72/157 reads (46%) | catalogued as COSV54324557; called by muse, mutect2, varscan2
- CCDC102A | c.1137G>A p.R379= | Silent (SNP) | VAF 70/206 reads (34%) | catalogued as COSV50778114; called by muse, mutect2, varscan2
- CD1E | c.108C>T p.S36= | Silent (SNP) | VAF 57/188 reads (30%) | catalogued as rs777079547, COSV63772116; called by muse, mutect2, varscan2
- CD300LG | c.369C>T p.F123= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs776427136, COSV53225012; called by muse, mutect2, varscan2
- CD34 | c.993G>A p.T331= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs764229152, COSV60414186; called by muse, mutect2, varscan2
- CD5L | c.51C>T p.F17= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV63821019, COSV63822774; called by muse, mutect2, varscan2
- CD7 | c.387C>T p.V129= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV53940200; called by muse, mutect2, varscan2
- CD7 | c.129C>T p.S43= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs139943005; called by muse, mutect2, varscan2
- CDH16 | c.1581G>A p.E527= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs1277996306, COSV55338448; called by muse, mutect2
- CDYL2 | c.1413G>A p.L471= | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as COSV73654508; called by muse, mutect2, varscan2
- CELA3A | c.99G>A p.E33= | Silent (SNP) | VAF 54/151 reads (36%) | catalogued as COSV51585603; called by muse, mutect2, varscan2
- CHERP | c.594G>A p.R198= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV52226547; called by muse, varscan2
- CLVS2 | c.654G>A p.L218= | Silent (SNP) | VAF 68/159 reads (43%) | catalogued as COSV51566593; called by muse, mutect2, varscan2
- CMTM6 | c.378C>T p.S126= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs558968197, COSV52750469, COSV99230215; called by muse, mutect2, varscan2
- CNTN1 | c.1674G>A p.R558= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV61641473; called by muse, mutect2, varscan2
- COL11A2 | c.327C>T p.V109= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as COSV59500066; called by muse, mutect2, varscan2
- COL4A1 | c.4308C>T p.P1436= | Silent (SNP) | VAF 49/190 reads (26%) | catalogued as rs1276174021, COSV65429157; called by muse, mutect2, varscan2
- COL6A3 | c.5217G>A p.L1739= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV55094927, COSV55100106; called by muse, mutect2, varscan2
- CPT1A | c.1131G>A p.E377= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs1215645933, COSV55759035; called by muse, mutect2, varscan2
- CRB2 | c.1881C>T p.F627= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV63504561; called by muse, mutect2, varscan2
- CSF2RA | c.996C>T p.I332= | Silent (SNP) | VAF 181/547 reads (33%) | catalogued as rs186573135, COSV62623481; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTAGE15 | c.1440G>A p.R480= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV101372146; called by mutect2, varscan2
- CX3CR1 | c.723C>T p.F241= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as rs1223432570, COSV64194619; called by muse, mutect2, varscan2
- CXADR | c.771C>T p.I257= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV53030214; called by muse, mutect2, varscan2
- CYP2C18 | c.622C>T p.L208= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs11188057, COSV53673898; called by muse, mutect2, varscan2
- DAXX | c.2019G>A p.L673= | Silent (SNP) | VAF 100/255 reads (39%) | catalogued as COSV56471492; called by muse, mutect2, varscan2
- DDIAS | c.735C>T p.F245= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV61272800; called by muse, mutect2, varscan2
- DEFB125 | c.87G>A p.K29= | Silent (SNP) | VAF 61/165 reads (37%) | catalogued as rs1193587492, COSV66703062, COSV66703499; called by muse, mutect2, varscan2
- DENND3 | c.657C>T p.F219= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as COSV52804780; called by muse, mutect2, varscan2
- DNAH9 | c.5682C>T p.F1894= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV52364611; called by muse, mutect2, varscan2
- DOK1 | c.492C>T p.A164= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV51206121; called by muse, mutect2, varscan2
- DUOX2 | c.3813G>A p.E1271= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as COSV66533339; called by muse, mutect2, varscan2
- ENPP6 | c.717G>A p.S239= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs144414378; called by muse, mutect2, varscan2
- EYA1 | c.477A>T p.G159= | Silent (SNP) | VAF 54/217 reads (25%) | catalogued as COSV58168959; called by muse, mutect2, varscan2
- F13B | c.1119G>A p.S373= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs748779845, COSV66373174; called by muse, mutect2, varscan2
- FAT1 | c.9168T>G p.A3056= | Silent (SNP) | VAF 31/191 reads (16%) | catalogued as COSV71675264; called by muse, mutect2, varscan2
- FILIP1 | c.474G>A p.Q158= | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as COSV52730750; called by muse, mutect2, varscan2
- FLG | c.9846C>T p.S3282= | Silent (SNP) | VAF 179/600 reads (30%) | catalogued as rs768693901, COSV64245277; called by muse, mutect2, varscan2
- FLNB | c.1326C>T p.F442= | Silent (SNP) | VAF 42/143 reads (29%) | catalogued as rs368128453; called by muse, mutect2, varscan2
- FMNL3 | c.1470C>T p.G490= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV53305433; called by muse, mutect2, varscan2
- FREM2 | c.2022C>T p.V674= | Silent (SNP) | VAF 38/137 reads (28%) | catalogued as COSV54845402; called by muse, mutect2, varscan2
- FRG2C | c.846C>T p.P282= | Silent (SNP) | VAF 28/191 reads (15%) | called by muse, mutect2, varscan2
- GABRB3 | c.1017G>A p.Q339= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as COSV54675671; called by muse, mutect2, varscan2
- GALNT2 | c.750A>G p.S250= | Silent (SNP) | VAF 42/164 reads (26%) | catalogued as COSV64196479; called by muse, mutect2, varscan2
- GJB5 | c.354G>A p.L118= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as COSV58356703; called by muse, mutect2, varscan2
- GLB1L2 | c.192C>T p.F64= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV60279778; called by muse, mutect2, varscan2
- GLYATL2 | c.768T>C p.F256= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV54850858; called by muse, mutect2, varscan2
- GPR139 | c.600C>T p.F200= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100429835, COSV58504035; called by muse, mutect2, varscan2
- GPR161 | c.1029G>A p.R343= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV54792692; called by muse, mutect2, varscan2
- GRIA1 | c.1587C>T p.F529= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as COSV53615181; called by muse, mutect2, varscan2
- GRN | c.783C>T p.L261= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV50008128; called by muse, mutect2, varscan2
- HDGFL1 | c.675G>A p.R225= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs754483486, COSV57752599; called by muse, mutect2, varscan2
- HPCAL1 | c.192C>T p.F64= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs267598821, COSV57145998; called by muse, mutect2, varscan2
- HPSE2 | c.1251C>T p.V417= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs1183638050, COSV65196207; called by muse, mutect2, varscan2
- HRH4 | c.897G>A p.R299= | Silent (SNP) | VAF 87/246 reads (35%) | catalogued as COSV56929046; called by muse, mutect2, varscan2
- HSD3B2 | c.54C>T p.I18= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs777605448, COSV101027465, COSV65592765; called by muse, mutect2, varscan2
- IGKV1-12 | c.348C>T p.F116= | Silent (SNP) | VAF 56/470 reads (12%) | called by muse, mutect2, varscan2
- IL36G | c.342G>A p.V114= | Silent (SNP) | VAF 68/227 reads (30%) | catalogued as rs917063043, COSV52078934; called by muse, mutect2, varscan2
- ING2 | c.309T>A p.I103= | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as COSV56564462; called by muse, mutect2, varscan2
- INHBA | c.414C>T p.F138= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54223558; called by muse, mutect2, varscan2
- INPP5B | c.2667C>T p.F889= (on ENST00000373023; = p.F809= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV65962067; called by muse, mutect2, varscan2
- INSRR | c.2280C>T p.F760= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs748185130, COSV63875800; called by muse, mutect2
- INSRR | c.1659C>T p.S553= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV63875808; called by muse, mutect2, varscan2
- INTS14 | c.444C>T p.F148= (on ENST00000313182 / NM_001366360.2; = p.F69= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV57528072; called by muse, mutect2, varscan2
- IP6K3 | c.576G>A p.E192= | Silent (SNP) | VAF 68/116 reads (59%) | catalogued as COSV53391205; called by muse, mutect2, varscan2
- ITGAD | c.3399G>A p.K1133= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs369919037; called by muse, mutect2, varscan2
- ITIH5 | c.894C>T p.F298= | Silent (SNP) | VAF 40/137 reads (29%) | catalogued as rs777406348, COSV53660883; called by muse, mutect2, varscan2
- KCNA6 | c.222C>T p.V74= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV99768671; called by muse, mutect2, varscan2
- KCNH4 | c.1149C>T p.I383= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs779840462, COSV52919917; called by muse, mutect2, varscan2
- KCNK9 | c.840G>A p.R280= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV57285693; called by muse, mutect2, varscan2
- KCNRG | c.285T>A p.V95= | Silent (SNP) | VAF 49/203 reads (24%) | catalogued as COSV53950675; called by muse, varscan2
- KIAA1841 | c.234G>A p.E78= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV54377254, COSV54377369; called by muse, mutect2, varscan2
- KIDINS220 | c.4795C>T p.L1599= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV56756933; called by muse, mutect2, varscan2
- KIF13A | c.4446C>T p.A1482= | Silent (SNP) | VAF 247/575 reads (43%) | catalogued as COSV52459925; called by muse, mutect2, varscan2
- KIR2DS4 | c.618G>A p.V206= | Silent (SNP) | VAF 94/180 reads (52%) | called by muse, mutect2, varscan2
- KLHL13 | c.1461A>T p.G487= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV53250913; called by muse, varscan2
- KRTAP10-11 | c.135G>T p.L45= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs1555939853, COSV58178902; called by muse, mutect2, varscan2
- KRTAP10-8 | c.186C>T p.T62= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs782128675, COSV100553821; called by muse, mutect2, varscan2
- LAG3 | c.1164A>G p.P388= | Silent (SNP) | VAF 54/171 reads (32%) | catalogued as COSV52568599; called by muse, mutect2, varscan2
- LGALS9 | c.837C>T p.R279= (on ENST00000395473 / NM_009587.3; = p.R247= on NM_002308.4) | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs762664779, COSV56350116; called by muse, mutect2, varscan2
- LRIF1 | c.2187C>T p.F729= | Silent (SNP) | VAF 58/196 reads (30%) | catalogued as rs747126394, COSV63897845; called by muse, mutect2, varscan2
- LRP5 | c.570G>A p.V190= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV53720353; called by muse, mutect2
- LTF | c.1863G>A p.R621= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as COSV51610472; called by muse, mutect2, varscan2
- MAFK | c.351C>T p.F117= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs543506128, COSV52474870; called by muse, mutect2, varscan2
- MAGEA6 | c.777G>A p.R259= | Silent (SNP) | VAF 67/133 reads (50%) | catalogued as rs1556826966, COSV100262834, COSV61449250; called by muse, mutect2, varscan2
- MAP2K3 | c.810C>T p.S270= (on ENST00000342679 / NM_145109.3; = p.S241= on NM_002756.4) | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV57573492; called by muse, mutect2, varscan2
- MATN3 | c.519C>T p.A173= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV68100338; called by muse, mutect2, varscan2
- MKS1 | c.528C>T p.I176= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV58304782; called by muse, mutect2
- MMP26 | c.660G>A p.G220= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV56173315; called by muse, mutect2, varscan2
- MORC2 | c.2925C>T p.A975= (on ENST00000397641 / NM_001303256.3; = p.A913= on NM_014941.3) | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV53200935; called by muse, mutect2, varscan2
- MPDZ | c.4125C>T p.V1375= | Silent (SNP) | VAF 24/39 reads (62%) | catalogued as COSV59921483; called by muse, mutect2, varscan2
- MRAS | c.297C>T p.S99= | Silent (SNP) | VAF 150/430 reads (35%) | catalogued as COSV56673158; called by muse, mutect2, varscan2
- MRPL37 | c.1053C>T p.V351= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as COSV60322262; called by muse, mutect2, varscan2
- MUC17 | c.10914C>T p.T3638= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV60297141; called by muse, mutect2, varscan2
- MYH4 | c.994C>T p.L332= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV55122975; called by muse, mutect2, varscan2
- MYO5C | c.3222C>T p.F1074= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as rs773376914, COSV55902641; called by muse, mutect2, varscan2
- NDUFB4 | c.9C>T p.F3= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV51742660; called by muse, mutect2, varscan2
- NECTIN1 | c.921C>T p.N307= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV50604050; called by muse, varscan2
- NEUROD1 | c.984C>T p.I328= | Silent (SNP) | VAF 187/666 reads (28%) | catalogued as COSV54550302; called by muse, mutect2, varscan2
- NEXMIF | c.1593A>G p.V531= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV50061480; called by muse, mutect2, varscan2
- NFATC2 | c.474C>T p.F158= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV65358986; called by muse, mutect2, varscan2
- NIBAN1 | c.1827G>A p.L609= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as rs1290634958, COSV62284574; called by muse, mutect2, varscan2
- NIPAL2 | c.885C>T p.I295= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV57842052; called by muse, mutect2, varscan2
- NLGN2 | c.1047C>T p.I349= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs373956106, COSV57211257; called by muse, mutect2, varscan2
- NLRP3 | c.1647G>A p.L549= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV60228914; called by muse, mutect2, varscan2
- NMBR | c.663C>T p.F221= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV57802487; called by muse, mutect2, varscan2
- NME8 | c.1656C>T p.I552= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs1441166335, COSV52253549; called by muse, mutect2, varscan2
- NOL10 | c.1893G>A p.L631= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV62041868; called by muse, mutect2, varscan2
- NPAS4 | c.207C>T p.L69= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV60651790; called by muse, mutect2, varscan2
- NPY2R | c.669C>T p.S223= | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as rs375533723; called by muse, mutect2, varscan2
- NUAK2 | c.1731C>T p.L577= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs1039630871, COSV65682177; called by muse, mutect2, varscan2
- NUAK2 | c.1569C>T p.S523= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV65682185; called by muse, mutect2
- NXPH2 | c.297G>A p.R99= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV55645223; called by muse, mutect2, varscan2
- OPHN1 | c.1956C>T p.S652= | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as COSV62784968; called by muse, mutect2, varscan2
- OPRL1 | c.468C>T p.I156= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as COSV61092391; called by muse, mutect2, varscan2
- OR10G4 | c.180C>T p.F60= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV100304752; called by muse, mutect2, varscan2
- OR10S1 | c.321C>T p.S107= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV73342925; called by muse, mutect2, varscan2
- OR1D2 | c.639C>T p.F213= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs376512950; called by muse, mutect2, varscan2
- OR1G1 | c.699G>A p.G233= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs146714964; called by muse, mutect2, varscan2
- OR2J3 | c.160C>T p.L54= | Silent (SNP) | VAF 73/355 reads (21%) | catalogued as COSV65849461; called by muse, mutect2, varscan2
- OR2Z1 | c.340C>T p.L114= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV60692971; called by muse, mutect2, varscan2
- OR4A47 | c.12G>A p.R4= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV71444964; called by muse, mutect2
- OR4C6 | c.873G>A p.E291= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV58604659, COSV58605317; called by muse, mutect2, varscan2
- OR4K14 | c.258C>T p.F86= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100520488, COSV59292890, COSV59293074; called by muse, mutect2, varscan2
- OR51V1 | c.771T>C p.P257= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV58315931; called by muse, mutect2, varscan2
- OR52E6 | c.639C>T p.L213= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV61432777; called by muse, mutect2, varscan2
- OR52N4 | c.606G>A p.L202= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100421781, COSV57892026; called by muse, mutect2, varscan2
- OR5H15 | c.826C>T p.L276= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV62948655; called by muse, mutect2, varscan2
- OR5P3 | c.261G>A p.R87= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV60428932; called by muse, mutect2, varscan2
- OR6K2 | c.942C>T p.S314= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs912488831, COSV62743100, COSV62744258; called by muse, mutect2, varscan2
- PCDHA10 | c.870G>A p.R290= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV56523335; called by muse, mutect2, varscan2
- PCDHB9 | c.345G>A p.Q115= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV53381726; called by muse, mutect2, varscan2
- PCDHGB1 | c.1882T>C p.L628= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV53995692; called by muse, mutect2, varscan2
- PCNT | c.5652G>A p.K1884= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV64026430; called by muse, mutect2
- PDE1C | c.1497C>T p.I499= | Silent (SNP) | VAF 41/143 reads (29%) | catalogued as COSV58521951; called by muse, mutect2, varscan2
- PDGFRB | c.2205G>A p.E735= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV55808168; called by muse, mutect2
- PES1 | c.1017C>T p.P339= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs768059240, COSV58829326; called by muse, mutect2, varscan2
- PGK2 | c.1198C>T p.L400= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as COSV59164797; called by muse, mutect2, varscan2
- PIK3R6 | c.426G>A p.Q142= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV61002957, COSV61004470; called by muse, mutect2, varscan2
- PKHD1L1 | c.10368C>T p.A3456= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs866576392, COSV65748604; called by muse, mutect2, varscan2
- PLAG1 | c.639C>T p.F213= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs756209071, COSV57613630; called by muse, mutect2, varscan2
- PLAGL2 | c.1108C>T p.L370= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV55789115; called by muse, mutect2, varscan2
- PLAGL2 | c.93C>T p.G31= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV55789126; called by muse, mutect2, varscan2
- PLD2 | c.918C>T p.I306= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV54007955; called by muse, mutect2, varscan2
- PLEKHA1 | c.1068C>T p.F356= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV64569921; called by muse, mutect2, varscan2
- PMFBP1 | c.711G>A p.E237= | Silent (SNP) | VAF 80/214 reads (37%) | catalogued as COSV52828997; called by muse, mutect2, varscan2
- PNN | c.120C>T p.I40= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs1280344037, COSV53767537; called by muse, mutect2, varscan2
- PPARA | c.150C>T p.G50= | Silent (SNP) | VAF 47/162 reads (29%) | catalogued as COSV53080375; called by muse, mutect2, varscan2
- PPARG | c.186C>T p.I62= (on ENST00000287820 / NM_015869.5; = p.I32= on NM_005037.7) | Silent (SNP) | VAF 221/823 reads (27%) | catalogued as COSV55144172; called by muse, mutect2, varscan2
- PRAM1 | c.351G>A p.K117= | Silent (SNP) | VAF 94/230 reads (41%) | catalogued as COSV55315584; called by muse, varscan2
- PRAMEF1 | c.522G>A p.R174= | Silent (SNP) | VAF 49/368 reads (13%) | catalogued as COSV60008224; called by muse, mutect2, varscan2
- PXDNL | c.2175G>A p.A725= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV62484198; called by muse, mutect2, varscan2
- RADX | c.399G>A p.R133= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as COSV100998846; called by muse, mutect2, varscan2
- RASSF2 | c.274C>T p.L92= | Silent (SNP) | VAF 50/161 reads (31%) | catalogued as COSV101040785; called by muse, mutect2, varscan2
- RASSF2 | c.273C>T p.N91= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as COSV101040787; called by muse, mutect2, varscan2
- RBP3 | c.426G>A p.E142= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs375546698; called by muse, mutect2, varscan2
- RGS9 | c.1299C>T p.L433= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as COSV99287527; called by muse, mutect2, varscan2
- RIPOR2 | c.1071C>T p.S357= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV52426233; called by muse, mutect2, varscan2
- RP1 | c.5532G>A p.K1844= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV55122241; called by muse, mutect2, varscan2
- RP2 | c.864C>T p.F288= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV54462758; called by muse, mutect2, varscan2
- RPIA | c.930C>T p.F310= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV52170946; called by muse, mutect2, varscan2
- RSRC1 | c.954G>A p.K318= | Silent (SNP) | VAF 47/164 reads (29%) | catalogued as rs747963263, COSV55834737; called by muse, mutect2, varscan2
- SAMD12 | c.18C>T p.L6= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100127113, COSV59054031; called by muse, mutect2, varscan2
- SCN1A | c.1224C>T p.F408= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV57664475, COSV57679850; called by muse, mutect2, varscan2
- SDR9C7 | c.903C>T p.I301= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV53290154; called by muse, mutect2, varscan2
- SEMA3C | c.1095C>T p.S365= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV54852322; called by muse, mutect2, varscan2
- SERPINA12 | c.75C>T p.F25= | Silent (SNP) | VAF 72/216 reads (33%) | catalogued as COSV57944966; called by muse, mutect2, varscan2
- SERPINA5 | c.573C>T p.L191= | Silent (SNP) | VAF 50/185 reads (27%) | catalogued as rs1803280, COSV61573880; called by muse, mutect2, varscan2
- SERPINA6 | c.1191C>T p.F397= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as rs267604110, COSV58583411, COSV58583818; called by muse, mutect2, varscan2
- SGMS1 | c.726C>T p.F242= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV62371642; called by muse, mutect2, varscan2
- SLC12A9 | c.1227C>T p.L409= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as rs771379238, COSV51935674; called by muse, mutect2, varscan2
- SLC15A3 | c.1236G>A p.A412= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs768264270, COSV50014361; called by mutect2, varscan2
- SLC22A25 | c.1098C>T p.G366= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs138188942; called by muse, mutect2, varscan2
- SLC22A3 | c.1278C>T p.F426= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV51715449; called by muse, mutect2, varscan2
- SLC22A8 | c.105C>T p.N35= | Silent (SNP) | VAF 88/236 reads (37%) | catalogued as COSV60326204; called by muse, mutect2, varscan2
- SLC24A3 | c.1752C>T p.S584= | Silent (SNP) | VAF 115/417 reads (28%) | catalogued as rs753628756, COSV60111643; called by muse, mutect2, varscan2
- SLC40A1 | c.78C>T p.F26= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV53724146; called by muse, mutect2, varscan2
- SLC44A2 | c.1662C>T p.F554= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as COSV59838074; called by muse, mutect2, varscan2
- SLCO1A2 | c.1384C>T p.L462= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs763490940, COSV56597178; called by muse, mutect2, varscan2
- SPTBN1 | c.4530C>T p.S1510= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV61691397; called by muse, mutect2, varscan2
- SQOR | c.1273C>T p.L425= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV52942820; called by muse, mutect2, varscan2
- SSX7 | c.408G>A p.G136= | Silent (SNP) | VAF 88/151 reads (58%) | catalogued as COSV53340811; called by muse, mutect2, varscan2
- STARD8 | c.2478C>T p.D826= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV52929834; called by muse, mutect2, varscan2
- STC1 | c.588C>T p.I196= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as COSV51689334; called by muse, mutect2, varscan2
- SUN5 | c.513G>A p.E171= | Silent (SNP) | VAF 103/308 reads (33%) | catalogued as COSV62181910; called by muse, mutect2, varscan2
- SYNE3 | c.552C>T p.I184= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as rs758570989, COSV62081148; called by muse, mutect2, varscan2
- TERT | c.1782G>A p.K594= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV57229191; called by muse, mutect2
- TMEM270 | c.279G>A p.Q93= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs782609664, COSV57639321; called by muse, mutect2, varscan2
- TNFAIP1 | c.862C>T p.L288= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV50228657; called by muse, mutect2, varscan2
- TNXB | c.3606C>T p.L1202= (on ENST00000647633; = p.L955= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/415 reads (20%) | catalogued as rs755735644, COSV64484297; called by muse, mutect2, varscan2
- TPO | c.972G>A p.L324= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV61107023; called by muse, mutect2, varscan2
- TRAV12-2 | c.219C>T p.S73= | Silent (SNP) | VAF 63/218 reads (29%) | called by muse, mutect2, varscan2
- TRIM3 | c.1416C>T p.L472= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs778651050, COSV61984610; called by muse, mutect2, varscan2
- TRIP10 | c.1371G>A p.L457= (on ENST00000313244 / NM_001288962.2; = p.L401= on NM_004240.4) | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV55587741; called by muse, mutect2, varscan2
30 further variants in this file (0 protein-altering or splice-affecting, 14 silent, 16 other) are not listed here.
